Somatic mutation profile of tumor specimen C3L-02897-01 (aliquot CPT0217700007) from CPTAC case C3L-02897, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 80.8 years (29,507 days).
Specimen C3L-02897-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c90f94a-a277-483b-9b49-dfbfe4b7a190.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02897-31 (Blood Derived Normal), aliquot CPT0219810002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/575d71e0-9304-4bf0-95da-a453d9188d04

The open-access MAF lists 39 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, Intron 4, Splice Site 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 31/240 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM8 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 36/353 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs746594474; called by muse, varscan2
- COLEC12 | c.1733G>C p.G578A | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1459310372, COSV101232129, COSV68372143; called by muse, mutect2
- CPEB3 | c.1927C>T p.R643C | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1302396098; called by muse, mutect2, varscan2
- DOCK2 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1487304870, COSV56943483; called by muse, mutect2
- FAM135B | c.2783G>A p.G928D | Missense Mutation (SNP) | VAF 31/317 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs755060753; called by muse, mutect2
- KDF1 | c.1040-1G>T p.X347_splice | Splice Site (SNP) | VAF 15/127 reads (12%) | catalogued as COSV57671038; called by muse, mutect2, varscan2
- OR2J3 | c.929G>A p.W310* | Nonsense Mutation (SNP) | VAF 7/93 reads (8%) | catalogued as rs947359693; called by muse, mutect2
- RAP1GAP2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV54582431; called by muse, mutect2
- SLC27A1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1249381073; called by muse, mutect2
- TM9SF2 | c.949A>T p.M317L | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV64507005; called by muse, mutect2
- TMPRSS11D | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs758167149, COSV52224233; called by muse, mutect2
- TRPA1 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772226867, COSV51560119; called by muse, mutect2, varscan2
- FAT4 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- GABPB1 | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- KLHL4 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PLEKHG4 | c.1582G>T p.G528W | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN12 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RANBP2 | c.239T>G p.V80G | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- RNF43 | c.582+2T>A p.X194_splice | Splice Site (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2
- SLC25A17 | c.550A>G p.M184V | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SPATA24 | c.497T>C p.M166T | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TCHH | c.3833A>G p.D1278G | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFEC | c.266C>A p.T89K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VARS1 | c.1230G>T p.E410D | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.371); called by muse, mutect2
- WBP1L | c.993C>A p.D331E | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.994); called by muse, mutect2
- YARS1 | c.441G>C p.K147N | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EXOSC2 | c.525C>A p.S175= | Silent (SNP) | VAF 13/148 reads (9%) | called by muse, mutect2
- NLRP6 | c.1788G>A p.G596= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs763627614; called by muse, mutect2, varscan2
- OR10G8 | c.66C>T p.D22= | Silent (SNP) | VAF 15/224 reads (7%) | catalogued as rs77692488; called by muse, mutect2
- PRMT1 | c.171C>T p.Y57= | Silent (SNP) | VAF 18/234 reads (8%) | catalogued as rs1407962473; called by muse, mutect2
- TENM2 | c.8082C>T p.R2694= (on ENST00000518659 / NM_001122679.2; = p.R2455= on NM_001080428.3) | Silent (SNP) | VAF 16/164 reads (10%) | catalogued as rs781070079; called by muse, mutect2
- UTF1 | c.522C>T p.N174= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- VPS35 | c.2040C>T p.G680= | Silent (SNP) | VAF 30/354 reads (8%) | called by muse, mutect2
- ANKS3 | c.1284+112C>T | Intron (SNP) | VAF 28/346 reads (8%) | catalogued as rs1340113670, COSV100422895; called by muse, mutect2
- PHF12 | c.2359+74T>G | Intron (SNP) | VAF 15/315 reads (5%) | called by muse, mutect2
- SATB2 | c.347-15915C>T | Intron (SNP) | VAF 5/100 reads (5%) | catalogued as rs1185221186; called by muse, mutect2
- SPSB3 | c.126+159G>A | Intron (SNP) | VAF 32/186 reads (17%) | catalogued as rs765592684; called by muse, mutect2, varscan2
- XIAP | c.*1445T>G | 3'UTR (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
